Somatic mutation profile of tumor specimen 0DMUZD from CCDI case PBBVMK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 15.2 years (5,565 days).
Specimen 0DMUZD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0e5f18e-961a-447f-ab14-86872bc0994e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMUX7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6af9735d-acb9-42bc-93f5-5377f4aec89c

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MCF2L | c.2756G>A p.R919H (on ENST00000375608; = p.R887H on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56175387, COSV99996173; called by muse, mutect2, varscan2
- BUB1B | c.967-62T>C | Intron (SNP) | VAF 38/123 reads (31%) | catalogued as rs547246737; called by muse, mutect2, varscan2
- OLFML2A | c.-56C>T | 5'UTR (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
